CCDI case PBBWNM — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Testis.
https://portal.gdc.cancer.gov/cases/e9d85778-6579-4423-b46b-cf83d925661c

Demographics
Sex at birth: male; Race: black or african american; Vital status: Alive.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 8.9 years (3,268 days).

Biospecimens (3 samples)
- Sample 0DJ9ZU: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DJ9ZY: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DJA06: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
